Gene-level copy-number profile of tumor specimen TCGA-XF-A9T5-01A from TCGA case TCGA-XF-A9T5, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 78.2 years (28,578 days).
Specimen TCGA-XF-A9T5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.a51cc246-1b2e-4639-8966-de050a21fdd8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XF-A9T5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/75999e94-8585-4b7e-bbc4-08bfd13bab9c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 47; copy number 1: 1,070; copy number 2: 16,947; copy number 3: 23,044; copy number 4: 13,363; copy number 5: 2,583; copy number 6: 407; copy number 7: 745; copy number 8: 1,523; copy number 11: 85.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XF-A9T5-01A-11D-A42D-01): tumor purity 0.45, ploidy 3.19, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 47 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:52,287,089–52,535,054, 12 genes: GLYCTK, GLYCTK-AS1, MIR135A1, DNAH1, PPP2R5CP, BAP1, PHF7, SEMA3G, TNNC1, NISCH, STAB1, NT5DC2.
- chr3:78,758,974–78,759,374, 1 gene: AC055731.1.
- chr9:21,802,636–24,905,735, 34 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,353 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–36,725,195, 564 genes, copy number 8 (broad region; genes not listed).
- chr7:70,837,738–109,660,802, 745 genes, copy number 7 (broad region; genes not listed).
- chr7:111,726,110–159,233,377, 959 genes, copy number 8 (broad region; genes not listed).
- chr8:36,784,324–36,936,125, 1 gene, copy number 11 (within-gene range 2–11): KCNU1.
- chr8:36,887,456–40,016,391, 84 genes, copy number 11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,070. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
